MMRF case MMRF_1758 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a9773efa-79a5-4137-ad21-27c9e808f1dd

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.5 years (26,473 days); ISS stage: II; Days to last known disease status: 1,168 days (3.2 years); Days to last follow up: 1,168 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 65 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 62 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 111 days; Days to treatment end: 111 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 112 days; Days to treatment end: 112 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 1.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 48.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 18.6 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 4.7 µg/mL; Lactate Dehydrogenase 5.93 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 144 µmol/L; Blood Urea Nitrogen 16.1 mmol/L; Calcium 3.38 mmol/L; Albumin 41 g/L; Total Protein 7.8 g/dL; Glucose 4.68 mmol/L.
- Day 106 (ECOG 2): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.967 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 6.4 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.83 µg/mL; Lactate Dehydrogenase 17.9 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 54.3 ×10⁹/L; Absolute Neutrophil 48.4 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 8.91 mmol/L.
- Day 198 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 4.97 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 7.43 mmol/L.
- Day 289 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.424 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.673 mg/dL; Immunoglobulin G 4.3 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.61 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 5.7 g/dL; Glucose 7.87 mmol/L.
- Day 376 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.549 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 5.4 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 6.49 mmol/L.
- Day 460 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.709 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 6.48 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 7.81 mmol/L.
- Day 552 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.903 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 7.47 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 6.16 mmol/L.
- Day 643 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.69 mg/dL; Immunoglobulin G 7.39 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 9.46 mmol/L.
- Day 734 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.983 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 7.55 g/L; Immunoglobulin A 1.52 g/L; Immunoglobulin M 0.59 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 11.7 mmol/L.
- Day 824 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 6.03 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.13 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 6.27 mmol/L.
- Day 922 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin G 5.81 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 7.26 mmol/L.
- Day 1,013 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 7.83 g/L; Immunoglobulin A 1.65 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 283 ×10⁹/L; Creatinine 137 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 6.93 mmol/L.
- Day 1,105 (ECOG 2): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 8.71 g/L; Immunoglobulin A 1.68 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 3.57 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 7.54 mmol/L.
- Day 1,168 (ECOG 2): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 8.56 g/L; Immunoglobulin A 1.61 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 134 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.63 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 6.77 mmol/L.

Other clinical attributes
- Day 0: Weight: 107 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Leukemia.

Biospecimens (2 samples)
- Sample MMRF_1758_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1758_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
